FM case AD4821 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/45d1cc76-f8de-422a-8239-98a3614ddb53

Male, 54.1 years: Carcinoma, NOS (ICD-O-3 8010/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
